Gene-level copy-number profile of tumor specimen TCGA-A7-A56D-01A from TCGA case TCGA-A7-A56D, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.3 years (30,783 days).
Specimen TCGA-A7-A56D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.71bafb6d-c0cd-499e-98cb-12bca4360593.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A56D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf3acd92-50eb-43d3-b11c-f5b53a18e38a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 313; copy number 2: 12,736; copy number 3: 9,783; copy number 4: 22,979; copy number 5: 6,980; copy number 6: 3,611; copy number 7: 2,553; copy number 8: 146; copy number 9: 113; copy number 10: 162; copy number 11: 95; copy number 12: 18; copy number 15: 21; copy number 17: 57; copy number 20: 49; copy number 21: 142; copy number 23: 3; copy number 28: 11; copy number 37: 37; copy number 39: 5; copy number 56: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A56D-01A-11D-A27O-01): tumor purity 0.64, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 554 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:32,427,901–32,951,656, 18 genes, copy number 12: AC018637.1, AC018641.1, SLC25A5P5, LSM5, AVL9, DPY19L1P1, ZNRF2P1, MIR550A2, MIR550B2, AC018645.3, LINC00997, AC018645.1, AC018645.2, DPY19L1P2, AC018648.1, KBTBD2, RP9P, AC083863.1.
- chr7:43,866,558–45,392,205, 63 genes, copy number 9–20 (broad region; genes not listed).
- chr17:26,981,694–29,930,276, 162 genes, copy number 17–21 (within-gene range 2–21) (broad region; genes not listed).
- chr17:39,165,073–39,564,907, 11 genes, copy number 28 (within-gene range 2–28): AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12, RNU6-233P.
- chr17:59,106,598–60,431,426, 58 genes, copy number 15–37 (within-gene range 2–37): AC099850.1, SKA2, RNU2-58P, MIR454, MIR301A, PRR11, SPDYE22P, AC099850.2, AC099850.3, SMG8, GDPD1, Y_RNA, SNRPGP17, YPEL2, AC091059.2, MIR4729, AC091059.1, LINC01476, RNU4-13P, DHX40, AC091271.1, CLTC, PTRH2, VMP1, AC040904.1, MIR21, RNU6-450P, TUBD1, NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64.
- chr17:61,590,421–61,863,528, 2 genes, copy number 23: NACA2, BRIP1.
- chr17:61,874,084–61,874,182, 1 gene, copy number 23: Y_RNA.
- chr17:62,231,470–64,542,461, 95 genes, copy number 11 (broad region; genes not listed).
- chr17:67,825,503–68,524,949, 27 genes, copy number 9 (within-gene range 2–9): BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635.
- chr20:31,303,212–32,809,356, 65 genes, copy number 9 (broad region; genes not listed).
- chr20:51,386,957–55,781,231, 52 genes, copy number 17–56: NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1.

Autosomal genes at a single copy (total copy number 1): 313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
